Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A3K1, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A3K1-01A (Primary Tumor).

[page 1 of 3]
Specimens Submitted:

- 1: SP: Left pararectal implant (fs)
- 2: SP: Left tube and ovary and tumor from left ureter and sigmoid colon (fs)
- 3: SP: Uterus, cervix, bilateral parametrium; radical hysterectomy
- 4: SP: Right tube and ovary with tumor from right ureter
- 5: SP: Cul-de-sac tumor
- 6: SP: Left obturator lymph node
- 7: SP: Left external iliac lymph nodes
- 8: SP: Right external iliac lymph nodes
- 9: SP: Right obturator lymph nodes
- 10: SP: Right hypogastric lymph nodes
- 11: SP: Tumor from rectum
- 12: SP: Omentum
- 13: SP: Falciiform ligament
- 14: SP: Right diaphragm peritoneum
- 15: SP: Tumor right Gerota's fascia
- 16: SP: Porta hepatis lymph node
- 17: SP: Proximal right ovarian vessel
- 18: SP: Right para-aortic nodes
- 19: SP: Right common iliac nodes
- 20: SP: Left renal lymph node
- 21: SP: Interaortocaval lymph node
- 22: SP: Precaval lymph node
- 23: SP: Inferior mesenteric lymph node
- 24: SP: High left para-aortic lymph node
- 25: SP: Rectosigmoid and tumor
- 26: SP: Proximal and distal margins colon

DIAGNOSIS:

1. Left pararectal implant; biopsy:
- Benign fibroadipose tissue.
2. Left Fallopian tube and ovary and tumor from left ureter and sigmoid colon; resection:
- Metastatic serous carcinoma involving left fallopian tube and ovary ✓
- Tumor also involves periadnexal soft tissue
- No ureter or colon is identified

** Continued on next page **

100-0-3

carcinoma, (papillary) serous 8441/3
Site: Endometrium C54.1 lw 12/20/11

[page 2 of 3]
3. SP: Uterus, cervix, bilateral parametrium; radical hysterectomy:

Tumor Type:

Adenocarcinoma, serous (papillary serous) type

Myometrial Invasion:

(>50%)

Measures 10mm in maximum depth

Myometrium thickness measures 17mm in the area of maximal tumor

invasion

Endocervical Invasion:

Mucosa and stroma

Parametrial tissue is also involved by tumor

Depth of cervical stromal invasion:

Measures 15.5mm

Cervical wall thickness measures 16mm in the area of maximum tumor

invasion

Lymphovascular invasion:

Identified

Endometrium:

Exhibits atrophy

Myometrium:

Unremarkable

Vaginal cuff margin is benign

4. Right Fallopian tube and ovary and tumor from right ureter; resection:
- Metastatic serous carcinoma involving right fallopian tube and ovary

5. Cul-de-sac tumor; excision:
- Metastatic serous carcinoma

6. Lymph nodes, left obturator; lymphadenectomy:
- Six benign lymph nodes (0/6).

7. Lymph nodes, left external iliac; lymphadenectomy:
- Metastatic carcinoma in one of six lymph nodes (1/6)

8. Lymph nodes, right external iliac; lymphadenectomy:
- Metastatic carcinoma in one of six lymph nodes (1/6)

9. Lymph nodes, right obturator; lymphadenectomy:
- Eight benign lymph nodes (0/8)

10. Lymph nodes, right hypogastric; lymphadenectomy:
- Metastatic carcinoma in one lymph node (1/1)

11. Tumor from rectum; excision:
- Benign fibroadipose tissue
- One benign lymph node (0/1)

12. Omentum; omentectomy:
- Metastatic serous carcinoma

13. Falciform ligament; excision:

** Continued on next page **

[page 3 of 3]
- Benign fibrous tissue

14. Right diaphragm peritoneum; excision:
- Metastatic serous carcinoma
15. Tumor right Gerota's fascia; excision:
- Cauterized fibrous tissue.
- No carcinoma seen
16. Lymph nodes, Porta hepatis; lymphadenectomy:
- Seven benign lymph nodes (0/7)
17. Proximal right ovarian vessel; excision:
- Serous carcinoma involving small vessel
18. Lymph nodes, Right para-aortic; lymphadenectomy:
- Right benign lymph nodes (0/8)
19. Lymph nodes, Right common iliac; lymphadenectomy:
- Six benign lymph nodes (0/6)
20. Lymph nodes, Left renal; lymphadenectomy:
- Metastatic carcinoma in four of six lymph nodes (4/6)
21. Lymph nodes, Interaortocaval; lymphadenectomy:
- Six benign lymph nodes (0/6)
22. Lymph nodes, Precaval; lymphadenectomy:
- Metastatic carcinoma in two lymph nodes (2/2)
23. Lymph nodes, Inferior mesenteric; lymphadenectomy:
- Metastatic carcinoma in four lymph nodes (4/4)
24. Lymph nodes, high left para-aortic; lymphadenectomy:
- Metastatic carcinoma in two of three lymph nodes (2/3)
25. Rectosigmoid and tumor; excision:
- Metastatic carcinoma involving peri-rectal adipose tissue
- Benign colonic mucosa
26. Colon, Proximal and distal margins; resection:
- Benign colonic tissue

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 6c7f9fc6-1529-43b5-88b3-b99ffdcaebb7 (TCGA-AP-A3K1.A2E4C9FE-F82D-440E-AA52-88379EBC2442.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).